Gene-level copy-number profile of tumor specimen REBC-AF7D-TTP1 from REBC case REBC-AF7D, project REBC-THYR (Comprehensive genomic characterization of radiation-related papillary thyroid cancer in the Ukraine). Sex at birth: male; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland.
Specimen REBC-AF7D-TTP1: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0f9121e0-10ad-4c3b-8991-848e8b48b6d4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator REBC-AF7D-NB1-SC208319 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,709 have no estimate.
https://portal.gdc.cancer.gov/files/176f697e-c976-4d95-a64f-d71d6d825cc2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 20; copy number 1: 3,133; copy number 2: 55,756; copy number 3: 5.

Homozygous deletions (total copy number 0; autosomes only): 20 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:28,362,796–28,685,264, 20 genes (within-gene range 0–2): AC091304.3, GOLGA8F, RN7SL238P, ABCB10P3, AC091304.8, AC091304.5, MIR4509-2, AC091304.2, AC138749.4, MIR4509-3, AC138749.7, ABCB10P4, GOLGA8G, Metazoa_SRP, AC138749.3, AC138749.1, AC138749.2, HERC2P11, HERC2P9, AC055876.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 277. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
